Somatic mutation profile of tumor specimen TCGA-CF-A47T-01A (aliquot TCGA-CF-A47T-01A-11D-A23U-08) from TCGA case TCGA-CF-A47T, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: Low Grade; Age at diagnosis: 58.4 years (21,347 days).
Specimen TCGA-CF-A47T-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 752ea47b-9498-4560-a373-8ef6f2b680f7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CF-A47T-10A (Blood Derived Normal), aliquot TCGA-CF-A47T-10A-01D-A23U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/25ba0aa2-ae69-40f7-b5f5-e7d0bc33e205

The open-access MAF lists 27 somatic variants for this specimen: 21 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 4, Nonsense Mutation 3, Intron 2, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 13/53 reads (25%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.251); catalogued as rs104894226, CM053285, COSV54237021, COSV54237051; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- ABCB4 | c.206C>T p.S69L | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.02); catalogued as COSV99711474; called by muse, mutect2
- CAD | c.807G>A p.M269I | Missense Mutation (SNP) | VAF 39/76 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); catalogued as rs1182586590, COSV53032767; called by muse, mutect2, varscan2
- COL11A1 | c.3356C>T p.A1119V | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as COSV62200452; called by muse, mutect2, varscan2
- CROT | c.472C>G p.Q158E | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1239613044, COSV100519656, COSV58977291; called by muse, mutect2
- GABRQ | c.1216G>C p.A406P | Missense Mutation (SNP) | VAF 47/103 reads (46%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as COSV64784291; called by muse, mutect2, varscan2
- GNL3 | c.1211A>T p.H404L | Missense Mutation (SNP) | VAF 61/132 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV56478955; called by muse, mutect2, varscan2
- HECA | c.961C>T p.H321Y | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.689); catalogued as rs776672994, COSV62770874; called by muse, mutect2, varscan2
- MCM7 | c.1099C>T p.R367* | Nonsense Mutation (SNP) | VAF 22/434 reads (5%) | catalogued as rs758325786, COSV57993915; called by muse, mutect2
- MID1 | c.1931G>A p.W644* | Nonsense Mutation (SNP) | VAF 44/94 reads (47%) | catalogued as COSV100452770; called by muse, mutect2, varscan2
- MUC17 | c.5692G>C p.V1898L | Missense Mutation (SNP) | VAF 156/350 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.092); catalogued as COSV60306656; called by muse, mutect2, varscan2
- PWWP3B | c.1138C>T p.R380C | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as rs373158939, COSV61799340; called by muse, mutect2, varscan2
- RFPL2 | c.659T>C p.L220P | Missense Mutation (SNP) | VAF 69/132 reads (52%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.611); catalogued as COSV50719778; called by muse, mutect2, varscan2
- SERPINH1 | c.1146C>A p.F382L | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63997694; called by muse, mutect2, varscan2
- SLITRK4 | c.1892C>T p.T631M | Missense Mutation (SNP) | VAF 44/127 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs782534462, COSV62022405; called by muse, mutect2, varscan2
- SORCS3 | c.1888G>T p.V630F | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.258); catalogued as COSV63828108; called by muse, mutect2, varscan2
- STAT6 | c.2224C>T p.Q742* | Nonsense Mutation (SNP) | VAF 34/78 reads (44%) | catalogued as rs1417949144, COSV100272827; called by muse, mutect2, varscan2
- TRPV3 | c.1196C>T p.T399M | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.197); catalogued as rs367883200, COSV56796486; called by muse, mutect2, varscan2
- VWF | c.7676C>T p.S2559L | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs778732929, COSV54611097; called by muse, mutect2, varscan2
- KMT2D | c.6764_6768del p.L2255Cfs*3 | Frame Shift Del (DEL) | VAF 19/53 reads (36%) | called by mutect2, pindel, varscan2
- SIRT7 | c.771dup p.A258Cfs*31 | Frame Shift Ins (INS) | VAF 28/66 reads (42%) | called by mutect2, pindel, varscan2
- C5AR1 | c.333C>T p.I111= | Silent (SNP) | VAF 46/95 reads (48%) | catalogued as COSV61893638; called by muse, mutect2, varscan2
- SALL3 | c.1476C>T p.P492= | Silent (SNP) | VAF 13/14 reads (93%) | catalogued as COSV73306365; called by muse, mutect2, varscan2
- TRIM42 | c.1791C>T p.N597= | Silent (SNP) | VAF 56/131 reads (43%) | catalogued as rs1021590216, COSV53887584; called by muse, mutect2, varscan2
- ZNF781 | c.48T>C p.C16= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as COSV62203179; called by muse, mutect2, varscan2
- GRHL3 | c.1694+4286_1694+4287insGGTTGAGC | Intron (INS) | VAF 13/59 reads (22%) | called by mutect2, pindel, varscan2
- HRAS | c.450+68_450+108del | Intron (DEL) | VAF 12/32 reads (38%) | called by mutect2, pindel
